Somatic mutation profile of tumor specimen d1e36453-8d78-4247-8c3c-3b2a6f (aliquot d1e36453-8d78-4247-8c3c-3b2a6f_D6_1) from CPTAC case 05BR026, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.4 years (26,097 days).
Specimen d1e36453-8d78-4247-8c3c-3b2a6f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22a145a6-df80-4115-a9cf-183d4f9e63bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a361c808-b55e-451f-be99-1fb391 (Blood Derived Normal), aliquot a361c808-b55e-451f-be99-1fb391_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a9cb7ca-f225-4801-8c44-4d6a45065e43

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 8, RNA 1, Intron 1, Splice Region 1, Translation Start Site 1, Nonsense Mutation 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AANAT | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs780636030; called by muse, mutect2, varscan2
- AOC1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs376059379; called by muse, mutect2, varscan2
- CHRD | c.2292G>A p.E764= | Splice Region (SNP) | VAF 36/230 reads (16%) | catalogued as COSV52606144; called by muse, mutect2, varscan2
- CUBN | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs756276102; called by muse, mutect2, varscan2
- FAT4 | c.3413C>G p.S1138C | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV101272516, COSV67893400; called by muse, mutect2, varscan2
- INPPL1 | c.1789C>G p.L597V | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs925900375; called by muse, mutect2, varscan2
- MMEL1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.906); catalogued as rs568619305, COSV99984185; called by muse, mutect2, varscan2
- MTA1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs782533215; called by muse, mutect2, varscan2
- MYO16 | c.4810G>A p.A1604T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.003); catalogued as COSV100697352; called by muse, mutect2, varscan2
- NTN3 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs760845427, COSV53546726, COSV99564955; called by muse, mutect2, varscan2
- PCDHB13 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as rs576971217, COSV53397023, COSV99507003; called by muse, mutect2, varscan2
- RP1L1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776560263, COSV61446208; called by muse, mutect2, varscan2
- TBX15 | c.1496G>A p.S499N (on ENST00000369429 / NM_001330677.2; = p.S393N on NM_152380.3) | Missense Mutation (SNP) | VAF 133/646 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as COSV52875099; called by muse, mutect2, varscan2
- UVSSA | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs772921989; called by muse, mutect2, varscan2
- ADAM19 | c.2591C>A p.A864E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTNAP2 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTTNBP2 | c.2384T>G p.L795* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- FMR1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LHX1 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- MSL1 | c.716A>T p.Q239L | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.242); called by muse, mutect2
- NUP210L | c.2881T>A p.L961M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDCD11 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASL11B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- RUNX1 | c.284_289del p.G95_D96del (on ENST00000344691 / NM_001001890.3; = p.G122_D123del on NM_001754.5) | In Frame Del (DEL) | VAF 25/186 reads (13%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2
- SPTBN5 | c.7369A>G p.S2457G | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SWAP70 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.517); called by muse, mutect2
- AGXT | c.1029C>T p.F343= | Silent (SNP) | VAF 69/463 reads (15%) | catalogued as rs748054201, COSV56755852; called by muse, mutect2
- DRC1 | c.1452G>A p.P484= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs1417232935; called by muse, mutect2, varscan2
- FLG | c.7287A>G p.G2429= | Silent (SNP) | VAF 142/833 reads (17%) | catalogued as rs950160236; called by muse, mutect2, varscan2
- NWD1 | c.1617G>A p.A539= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as rs367553720; called by muse, mutect2, varscan2
- RERE | c.1398C>T p.T466= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs139017986; called by muse, mutect2, varscan2
- SALL4 | c.2760C>T p.H920= | Silent (SNP) | VAF 26/312 reads (8%) | catalogued as rs561427172, COSV53855533; called by muse, mutect2
- SLC66A1 | c.240C>T p.G80= | Silent (SNP) | VAF 33/199 reads (17%) | catalogued as rs537651536; called by muse, mutect2, varscan2
- SPATA31E1 | c.2370C>G p.L790= | Silent (SNP) | VAF 34/253 reads (13%) | catalogued as COSV57791676; called by muse, mutect2, varscan2
- FAN1 | c.-98G>C | 5'UTR (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- IGFN1 | c.1242-3407G>A | Intron (SNP) | VAF 20/424 reads (5%) | called by muse, mutect2
- NBPF25P | n.1082A>T | RNA (SNP) | VAF 96/657 reads (15%) | called by muse, mutect2, varscan2
